CPTAC case C3N-00662 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1827eb4b-38f3-45b5-a833-156ba748c784

Demographics
Sex at birth: female; Race: white; Year of birth: 1939; Vital status: Dead; Days to death: 116 days; Year of death: 2017; Cause of death: Infection; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 77.8 years (28,406 days); Year of diagnosis: 2016; Days to last known disease status: 116 days; Days to last follow up: 116 days.
   Pathology details: Greatest tumor dimension: 3 cm.

Follow-up (1 entry)
- Days to follow up: 116 days; Karnofsky performance status: 80; ECOG performance status: 1.

Other clinical attributes
- Weight: 61 kg; Height: 153 cm; BMI: 26.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 57; Cigarettes per day: 20; Tobacco smoking onset year: 1959; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 63.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00662-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 853 mg.
- Sample C3N-00662-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 756 mg.
- Sample C3N-00662-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 623 mg; Time between excision and freezing: 6 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00662-23: Section location: Temporal Lobe; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3N-00662-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -10 days; Method of sample procurement: Blood Draw.
- Sample C3N-00662-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
